Somatic mutation profile of tumor specimen MP2PRT-PARRXA-TMP1-A (aliquot MP2PRT-PARRXA-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PARRXA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.5 years (5,675 days).
Specimen MP2PRT-PARRXA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bea71b94-6b70-429d-9822-008fef5ed914.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARRXA-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARRXA-NM1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d57ddb33-3140-4b6c-98e7-75ead0aa04b8

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Nonsense Mutation 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM71B | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 232/466 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs112210804, COSV57228795; called by muse, mutect2, varscan2
- HEATR1 | c.4846C>T p.R1616C | Missense Mutation (SNP) | VAF 55/519 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372362755; called by muse, mutect2, varscan2
- IFNL2 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 218/551 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs373525938; called by muse, mutect2, varscan2
- MUC16 | c.14515G>A p.G4839S | Missense Mutation (SNP) | VAF 167/351 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs772154270; called by muse, mutect2, varscan2
- NUMBL | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 254/569 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1318909322, COSV53284451; called by muse, mutect2, varscan2
- OR13C3 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 115/264 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV101053323; called by muse, mutect2, varscan2
- SNX16 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 86/203 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs867753958, COSV62036088; called by muse, mutect2, varscan2
- TAF1D | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 17/324 reads (5%) | catalogued as rs948843593; called by muse, mutect2
- ADAM30 | c.964A>G p.S322G | Missense Mutation (SNP) | VAF 19/392 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.223); called by muse, mutect2
- ARSK | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BTBD10 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 60/336 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CERCAM | c.1742G>A p.G581D | Missense Mutation (SNP) | VAF 223/520 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- FAM83A | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 63/661 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); called by muse, mutect2
- GOLGA8Q | c.407A>G p.Q136R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); called by mutect2, varscan2
- LIG4 | c.2351C>G p.S784C | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2
- MMP12 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNKS2 | c.1732C>T p.L578F | Missense Mutation (SNP) | VAF 21/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRMT2B | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- ABLIM3 | c.372C>T p.S124= | Silent (SNP) | VAF 23/395 reads (6%) | catalogued as rs562950851, COSV58639499; called by muse, mutect2
- COL24A1 | c.1734A>C p.P578= | Silent (SNP) | VAF 132/338 reads (39%) | called by muse, mutect2, varscan2
- FSIP2 | c.135G>A p.P45= | Silent (SNP) | VAF 15/429 reads (3%) | catalogued as rs1452000513; called by muse, mutect2
- NDN | c.465G>A p.L155= | Silent (SNP) | VAF 20/489 reads (4%) | called by muse, mutect2
- PCLO | c.14367G>A p.V4789= | Silent (SNP) | VAF 103/235 reads (44%) | called by muse, mutect2, varscan2
- TNN | c.2565G>A p.L855= | Silent (SNP) | VAF 104/530 reads (20%) | called by muse, mutect2, varscan2
- FAM182B | n.415C>T | RNA (SNP) | VAF 77/374 reads (21%) | catalogued as rs556799203; called by muse, mutect2, varscan2
- NPIPA5 | c.642+73C>T | Intron (SNP) | VAF 28/66 reads (42%) | catalogued as rs1371778017; called by mutect2, varscan2
